CCDI case PBBWHU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/2ad56939-7f02-42d0-9edc-46b094e0827b

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.5 years (5,291 days).

Biospecimens (3 samples)
- Sample 0DIW6C: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DIW78: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DIW88: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
